Somatic mutation profile of tumor specimen TCGA-D3-A8GO-06A (aliquot TCGA-D3-A8GO-06A-11D-A372-08) from TCGA case TCGA-D3-A8GO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A8GO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f667969c-b27c-44cc-8168-be91c8dad3f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GO-10A (Blood Derived Normal), aliquot TCGA-D3-A8GO-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8cd0245-27db-4fd2-97d5-4661b8b00473

The open-access MAF lists 701 somatic variants for this specimen: 432 protein-altering or splice-affecting, 249 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 387, Silent 249, Nonsense Mutation 31, RNA 8, Intron 7, Frame Shift Ins 4, Frame Shift Del 3, Splice Site 3, Splice Region 2, 5'Flank 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs724159990, CM1515335, COSV99190889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs202247795, COSV104368601, COSV53499570; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV99815771; called by muse, mutect2
- ABCA13 | c.3448T>G p.W1150G | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101329935; called by muse, mutect2, varscan2
- ABCA8 | c.3979G>A p.E1327K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52201315; called by muse, mutect2, varscan2
- ABCB1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762322710, COSV55946596, COSV55951669; called by muse, mutect2, varscan2
- ABCC6 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as COSV99228107; called by muse, mutect2, varscan2
- AC090517.4 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs1454250035, COSV99974119; called by muse, mutect2, varscan2
- AC090517.4 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV99974121; called by muse, mutect2, varscan2
- AC104389.6 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100400572; called by muse, mutect2, varscan2
- ACSM2B | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1332959076, COSV100312337; called by muse, mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADAM7 | c.1997T>C p.V666A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV99443057; called by muse, mutect2, varscan2
- ADAMTS20 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs751344474, COSV67136679; called by muse, mutect2
- ADCY10 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1285446312, COSV100896587; called by muse, mutect2, varscan2
- AHNAK | c.15553C>T p.P5185S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs543982244, COSV99945745; called by muse, mutect2, varscan2
- AHNAK | c.4546C>T p.P1516S | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99945748, COSV99946093; called by mutect2, varscan2
- AKAP9 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as rs779398715, COSV62339967; called by muse, mutect2, varscan2
- AKAP9 | c.6262C>T p.Q2088* (on ENST00000359028; = p.Q2056* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100661919, COSV100661939; called by muse, mutect2, varscan2
- ALK | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs1208550472, COSV66559433; called by muse, mutect2, varscan2
- ANK1 | c.2999G>A p.G1000D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV99224090; called by muse, mutect2, varscan2
- ANKZF1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs555146150, COSV99850266; called by muse, mutect2, varscan2
- APCS | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99661194; called by muse, mutect2, varscan2
- ARAP1 | c.3391C>T p.L1131F (on ENST00000393609 / NM_001040118.2; = p.L886F on NM_015242.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100501581; called by muse, mutect2, varscan2
- ARF3 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.089); catalogued as rs754594826, COSV99873024; called by muse, mutect2, varscan2
- ARHGAP27 | c.1870G>A p.E624K (on ENST00000428638 / NM_001282290.1; = p.E283K on NM_199282.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs771562751, COSV65356979; called by muse, mutect2, varscan2
- ARHGEF18 | c.3233C>T p.S1078F (on ENST00000359920 / NM_001130955.2; = p.S974F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV100149750, COSV60467359; called by muse, mutect2, varscan2
- ARMC12 | c.845C>T p.S282F (on ENST00000373866 / NM_001286574.2; = p.S309F on NM_145028.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV99849357; called by muse, mutect2
- ARMC4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99518237; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100771819; called by muse, mutect2, varscan2
- ATAD3B | c.548C>T p.S183F (on ENST00000308647; = p.S289F on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100426289; called by muse, mutect2, varscan2
- ATP9A | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58771809; called by muse, mutect2
- BBS9 | c.1684C>T p.L562F (on ENST00000242067 / NM_001348036.1; = p.L522F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54162648; called by muse, mutect2, varscan2
- BMP3 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99261408; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMP5 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as rs200941967, COSV63701586; called by muse, mutect2, varscan2
- BNIP1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.329); catalogued as rs1220010096, COSV99199369; called by muse, mutect2, varscan2
- C11orf94 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs1027546854, COSV99571119; called by muse, mutect2, varscan2
- C16orf71 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100172797; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, mutect2, varscan2
- C2 | c.2053C>T p.L685F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV100190683; called by muse, mutect2, varscan2
- CACNA1E | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs770455581, COSV62437732; called by muse, mutect2, varscan2
- CACNA2D1 | c.2678C>T p.A893V (on ENST00000356253 / NM_001366867.1; = p.A881V on NM_000722.4) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV62393077; called by muse, mutect2, varscan2
- CAD | c.5099C>T p.P1700L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV53033851; called by muse, mutect2, varscan2
- CAND2 | c.2917C>T p.P973S (on ENST00000456430 / NM_001162499.2; = p.P880S on NM_012298.3) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs769074929, COSV99928660; called by muse, mutect2, varscan2
- CAPN13 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as rs1262752487, COSV99699784; called by muse, mutect2, varscan2
- CATSPERB | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236657005, COSV99830853; called by muse, mutect2, varscan2
- CCDC114 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100196388; called by muse, mutect2, varscan2
- CD1E | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV63771420; called by muse, mutect2, varscan2
- CD244 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV100458253; called by muse, mutect2, varscan2
- CD300LB | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV100075310; called by muse, mutect2, varscan2
- CDH11 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 31/117 reads (26%) | catalogued as COSV99217319; called by muse, mutect2, varscan2
- CDH23 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1390133151, COSV54935060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH9 | c.2295T>A p.D765E | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV99141892; called by muse, mutect2, varscan2
- CDRT1 | c.2020C>T p.H674Y | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100599745; called by muse, mutect2, varscan2
- CDS2 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 156/369 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as COSV100986068; called by muse, mutect2, varscan2
- CFAP43 | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99530406; called by muse, mutect2, varscan2
- CHD9 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101271909; called by muse, mutect2, varscan2
- CIT | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55886691, COSV99948459; called by muse, mutect2, varscan2
- CLCA4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.219); catalogued as COSV99760244; called by muse, mutect2, varscan2
- CLEC7A | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as COSV100021036; called by muse, mutect2, varscan2
- CLGN | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1385879037, COSV100346396; called by muse, mutect2, varscan2
- CNOT4 | c.1477G>A p.G493S (on ENST00000315544 / NM_001190848.1; = p.G490S on NM_013316.4) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.151); catalogued as rs561377184, COSV100211113; called by muse, mutect2, varscan2
- COL5A1 | c.4965G>A p.W1655* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100879557, COSV100880405; called by muse, mutect2, varscan2
- CPE | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291547, COSV68581874; called by muse, mutect2
- CPED1 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1330057265, COSV100120040; called by muse, mutect2, varscan2
- CPNE4 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.259); catalogued as COSV70190065; called by muse, mutect2, varscan2
- CREB5 | c.1363+1G>A p.X455_splice (on ENST00000357727 / NM_182898.4; = p.X448_splice on NM_004904.3) | Splice Site (SNP) | VAF 20/148 reads (14%) | catalogued as rs1405706071, COSV100744179; called by muse, mutect2, varscan2
- CRNN | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 65/296 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs866624042, COSV55123673; called by muse, mutect2, varscan2
- CSMD2 | c.7942G>A p.D2648N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1163127634, COSV99586362; called by muse, mutect2, varscan2
- CSMD2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1436948628, COSV99586366; called by muse, mutect2
- CSMD2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1330969566, COSV99586370; called by muse, mutect2
- CUL9 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as COSV99334829; called by muse, mutect2, varscan2
- CWH43 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1346772230, COSV56938279; called by muse, mutect2, varscan2
- DAO | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.645); catalogued as rs758203634, COSV99948446; called by muse, mutect2, varscan2
- DDX20 | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV63778428; called by muse, mutect2
- DDX60L | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs368624817, COSV99487007, COSV99487270; called by muse, varscan2
- DEFB113 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1209328851, COSV59038214; called by muse, mutect2, varscan2
- DEFB118 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV53620718, COSV99489301; called by muse, mutect2, varscan2
- DENND2C | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101283891; called by muse, mutect2, varscan2
- DGKB | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1266187114, COSV51796132; called by muse, mutect2, varscan2
- DGKI | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55935459; called by muse, mutect2, varscan2
- DGKK | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.787); catalogued as COSV65709493; called by muse, mutect2, varscan2
- DGKK | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs782712184, COSV65706174; called by muse, mutect2, varscan2
- DHX36 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV100273341; called by muse, mutect2, varscan2
- DISP3 | c.3880G>A p.V1294I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.686); catalogued as rs775248733, COSV53823292; called by muse, varscan2
- DLG4 | c.792T>A p.Y264* (on ENST00000399506 / NM_001321075.3; = p.Y307* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100263455; called by muse, mutect2
- DMRT1 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs749484127, COSV101206615; called by muse, varscan2
- DNAH12 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV100244360; called by muse, mutect2
- DNAH2 | c.7352C>T p.S2451F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101209029; called by muse, mutect2, varscan2
- DNAH2 | c.8081-1G>A p.X2694_splice | Splice Site (SNP) | VAF 11/101 reads (11%) | catalogued as COSV101209030; called by muse, mutect2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH8 | c.12718G>A p.E4240K | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100543431; called by muse, mutect2, varscan2
- DNAH9 | c.4720G>A p.E1574K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99304279; called by muse, mutect2, varscan2
- DNAH9 | c.6881G>A p.W2294* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52348569; called by muse, mutect2, varscan2
- DNAH9 | c.13432G>A p.A4478T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99304285; called by muse, mutect2, varscan2
- DPP8 | c.2038C>T p.R680W (on ENST00000341861 / NM_001320875.2; = p.R664W on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs761602081, COSV55681404; called by muse, mutect2, varscan2
- DPPA4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509998; called by muse, mutect2, varscan2
- DRC1 | c.545T>A p.L182* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99985040; called by muse, mutect2
- DRC7 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100395380; called by muse, mutect2, varscan2
- DSG4 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV57394759; called by muse, mutect2, varscan2
- EDIL3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV99674881; called by muse, mutect2, varscan2
- EFCAB6 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99412511; called by muse, mutect2, varscan2
- EFNA5 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100320907; called by muse, mutect2, varscan2
- EGFLAM | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as rs1230455483, COSV100379859; called by muse, mutect2, varscan2
- EMILIN2 | c.2213G>A p.W738* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99598155; called by muse, mutect2, varscan2
- EPHA3 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60702501; called by muse, mutect2, varscan2
- EPN2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59060045; called by muse, mutect2, varscan2
- ERICH3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1319714520, COSV100443473; called by muse, mutect2, varscan2
- ERN1 | c.2491T>A p.F831I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV101458388; called by muse, mutect2, varscan2
- F9 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs756148155, CM132966, COSV54381418; called by muse, mutect2, varscan2
- FAM135B | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1563821067, COSV50525543, COSV50528630; called by muse, mutect2, varscan2
- FAM13B | c.1289T>G p.I430S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99221006; called by muse, mutect2, varscan2
- FAM161A | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100281133; called by muse, mutect2, varscan2
- FAM170A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100088748; called by muse, mutect2
- FAM47C | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792304; called by muse, mutect2, varscan2
- FAM76B | c.139T>A p.F47I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100334582; called by muse, mutect2, varscan2
- FASTK | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1471677189, COSV99879558; called by muse, mutect2, varscan2
- FAT4 | c.9937G>A p.A3313T | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100627311; called by muse, mutect2, varscan2
- FCER2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.455); catalogued as rs1396802189, COSV100689504; called by muse, mutect2, varscan2
- FGF12 | c.359G>A p.G120E (on ENST00000454309 / NM_021032.5; = p.G58E on NM_004113.6) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53164172; called by muse, mutect2, varscan2
- FIGN | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60767707; called by muse, mutect2, varscan2
- FLG2 | c.4853G>A p.G1618E | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV101165609; called by muse, mutect2, varscan2
- FLT4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986028; called by muse, mutect2, varscan2
- FMNL3 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV53303646, COSV99525656; called by muse, mutect2, varscan2
- FOXN2 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100488995; called by muse, mutect2, varscan2
- FUT3 | c.698C>G p.T233S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as COSV54606983, COSV99744281; called by muse, mutect2, varscan2
- GABRB2 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99195666; called by muse, mutect2, varscan2
- GABRQ | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941094; called by muse, mutect2, varscan2
- GAL3ST2 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752664663, COSV99510732; called by muse, mutect2, varscan2
- GLDC | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393818; called by muse, mutect2, varscan2
- GLS | c.1427T>C p.V476A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100289738; called by muse, mutect2, varscan2
- GLYCTK | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs754436038, COSV99980638; called by muse, mutect2, varscan2
- GRIP2 | c.2771C>T p.P924L (on ENST00000619221; = p.P827L on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1275925831, COSV99816965; called by muse, mutect2, varscan2
- GUCY1A2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1313859382, COSV99972932; called by muse, mutect2, varscan2
- GYS2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679328; called by muse, mutect2, varscan2
- H1-5 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776773973, COSV100137709; called by muse, mutect2, varscan2
- HECW1 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101222864; called by muse, mutect2, varscan2
- HK3 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1206360222, COSV99457898; called by muse, mutect2, varscan2
- HK3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs573086536, COSV52836822; called by muse, mutect2, varscan2
- HKDC1 | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100664382; called by muse, mutect2, varscan2
- HLA-DQB1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs760326072, COSV100891087; called by muse, varscan2
- HNF4G | c.593G>A p.G198E (on ENST00000354370 / NM_001330561.2; = p.G245E on NM_004133.5) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62965564; called by muse, mutect2, varscan2
- HOXA2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 76/175 reads (43%) | catalogued as COSV99761015; called by muse, mutect2, varscan2
- HSH2D | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53738329, COSV99507103, COSV99507180; called by muse, mutect2, varscan2
- HTR1E | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100540958; called by muse, mutect2, varscan2
- HYAL4 | c.1310G>C p.C437S | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV99772070; called by muse, mutect2, varscan2
- IKZF1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497983; called by muse, mutect2
- IL31RA | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV61692543; called by muse, mutect2, varscan2
- IMPG1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1562371855, COSV100885731, COSV64059618; called by muse, mutect2, varscan2
- INPPL1 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53354185; called by muse, mutect2, varscan2
- INTS6L | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100878023; called by muse, mutect2, varscan2
- IREB2 | c.2210T>G p.I737S | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99359058; called by muse, mutect2, varscan2
- ITGA10 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553748575, COSV65198432; called by muse, mutect2, varscan2
- ITGAM | c.1921G>A p.D641N (on ENST00000648685 / NM_001145808.2; = p.D640N on NM_000632.4) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54934912, COSV54942492; called by muse, mutect2, varscan2
- ITGB3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101457545; called by muse, mutect2, varscan2
- ITPR2 | c.3715C>T p.H1239Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101189824; called by muse, mutect2, varscan2
- JCAD | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100948101; called by muse, mutect2, varscan2
- KALRN | c.5380C>T p.R1794C (on ENST00000360013 / NM_001024660.4; = p.R97C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs143334749, COSV52260608; called by muse, mutect2, varscan2
- KAT2A | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.418); catalogued as COSV99863398; called by muse, mutect2, varscan2
- KCNA1 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101230129; called by muse, mutect2, varscan2
- KCNB2 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.192); catalogued as COSV101578671; called by muse, mutect2, varscan2
- KCND1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99501748; called by muse, mutect2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2
- KCNK17 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100950065; called by muse, mutect2, varscan2
- KIAA0513 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99260472; called by muse, mutect2, varscan2
- KIAA1109 | c.10384C>T p.P3462S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99145937; called by muse, mutect2, varscan2
- KIF14 | c.4490T>C p.V1497A | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV66259935; called by muse, mutect2, varscan2
- KIR2DL1 | c.720C>A p.N240K | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.13); catalogued as rs1471595630, COSV52409218; called by muse, mutect2, varscan2
- KIR2DL4 | c.970G>A p.V324M (on ENST00000396284; = p.V250M on NM_001080770.2) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as COSV100428290; called by muse, mutect2, varscan2
- KL | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV101199015; called by muse, mutect2, varscan2
- KLRG1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99868077; called by muse, mutect2, varscan2
- KRT35 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1390254622, COSV99877681; called by muse, mutect2, varscan2
- KRT71 | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV99921972; called by muse, mutect2, varscan2
- KRT81 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100576925; called by muse, mutect2, varscan2
- LCK | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781676626, COSV60739591; called by muse, mutect2, varscan2
- LCN2 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV99478137; called by muse, mutect2, varscan2
- LPIN3 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV64718728; called by muse, mutect2, varscan2
- LRFN1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99952648; called by muse, mutect2, varscan2
- LRG1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 97/372 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56702602; called by muse, varscan2
- LRP1B | c.11218G>A p.D3740N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1338371264, COSV101252998; called by muse, mutect2, varscan2
- LRP2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99786677; called by muse, mutect2, varscan2
- LRRC18 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99628515; called by muse, mutect2, varscan2
- LTBP4 | c.4393C>T p.P1465S (on ENST00000308370 / NM_001042544.1; = p.P1428S on NM_003573.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV52578975; called by muse, mutect2, varscan2
- MAB21L4 | c.646G>A p.G216R (on ENST00000388934 / NM_001085437.3; = p.G48R on NM_024861.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs772781785, COSV56743494; called by muse, mutect2, varscan2
- MAGEB6 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs1569256324, COSV100983661, COSV100983745; called by muse, mutect2, varscan2
- MAP2K6 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs371824152; called by muse, mutect2, varscan2
- MAP3K11 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1163029839, COSV100442045; called by muse, mutect2
- MARK1 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100857068; called by muse, mutect2, varscan2
- MATK | c.1487C>T p.A496V (on ENST00000310132 / NM_139355.3; = p.A497V on NM_002378.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100035864; called by muse, mutect2, varscan2
- MCTP1 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.05); catalogued as COSV100386363, COSV100387721; called by muse, mutect2, varscan2
- MEOX1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1392530268, COSV100233676; called by muse, mutect2, varscan2
- MGAM | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV72073539; called by muse, mutect2, varscan2
- MGAM | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs750406655, COSV72074599; called by muse, mutect2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MISP | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV99296603; called by muse, mutect2, varscan2
- MLIP | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99228555; called by muse, mutect2
- MLLT11 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV64461955; called by muse, mutect2, varscan2
- MROH7 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100272906; called by muse, mutect2, varscan2
- MTNR1B | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99924958; called by muse, mutect2, varscan2
- MTUS1 | c.3016C>T p.R1006W (on ENST00000262102 / NM_001363061.1; = p.R172W on NM_020749.4) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs368662263; called by muse, mutect2, varscan2
- MUC16 | c.32315C>T p.P10772L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as rs1232058550, COSV101198293; called by muse, mutect2, varscan2
- MUC16 | c.17057C>T p.S5686L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV67494359; called by muse, mutect2
- MUC16 | c.14218G>A p.D4740N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1214687860, COSV67506815; called by muse, mutect2, varscan2
- MUC16 | c.3712A>G p.T1238A | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs752427750, COSV67468588; called by muse, mutect2, varscan2
- MUTYH | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM056361, CM116658, COSV100587909, COSV58343464; called by muse, mutect2, varscan2
- MXRA5 | c.7232C>T p.S2411F | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as rs769124138, COSV99475895; called by muse, mutect2, varscan2
- MXRA5 | c.5781G>A p.M1927I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV99475897; called by muse, mutect2, varscan2
- MYBL1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV101576478; called by muse, mutect2, varscan2
- MYH8 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101238233; called by muse, mutect2, varscan2
- MYH8 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101238234; called by muse, mutect2, varscan2
- MYOCD | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100590227, COSV100591043; called by muse, mutect2, varscan2
- NBEA | c.4172A>G p.D1391G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100077051; called by muse, mutect2, varscan2
- NCOA1 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99945272; called by muse, mutect2
- NDUFS6 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1313855049, COSV99928913; called by muse, mutect2, varscan2
- NFAT5 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100590468; called by muse, mutect2, varscan2
- NHLRC3 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs898211561, COSV100612652; called by muse, mutect2, varscan2
- NIBAN1 | c.2741G>A p.G914E | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs1458303651, COSV62287636; called by muse, mutect2, varscan2
- NLRP10 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs1386744348, COSV100149487; called by muse, mutect2, varscan2
- NLRP11 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as rs1241942633, COSV64086443; called by muse, mutect2, varscan2
- NMUR2 | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV54920274; called by muse, mutect2, varscan2
- NNMT | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as COSV55474384; called by muse, mutect2, varscan2
- NOX5 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99533337; called by mutect2, varscan2
- NPHS1 | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as rs867310471, COSV62289531; called by muse, mutect2, varscan2
- NRG2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV99179935; called by muse, mutect2, varscan2
- NRG2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99179939, COSV99183677; called by muse, mutect2, varscan2
- NRXN1 | c.4209G>A p.M1403I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100639853; called by muse, mutect2, varscan2
- NTN4 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs750826644, COSV59219246; called by muse, mutect2, varscan2
- NUP35 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99717715; called by muse, mutect2, varscan2
- NWD1 | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100341787; called by muse, mutect2, varscan2
- NYNRIN | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV66844910; called by muse, mutect2
- OBSCN | c.12815G>A p.R4272Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as rs1202948679, COSV99473243; called by muse, mutect2
- OLFML3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.393); catalogued as rs778043649, COSV100232974; called by muse, mutect2, varscan2
- OPTC | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs538644252, COSV100557755; called by muse, mutect2, varscan2
- OR1D5 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV101643407; called by muse, varscan2
- OR2A12 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 64/341 reads (19%) | catalogued as COSV101283148; called by muse, mutect2, varscan2
- OR2G2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as COSV100189585; called by muse, mutect2, varscan2
- OR51G2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs201238790; called by muse, mutect2, varscan2
- OR5M1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV73202093; called by muse, mutect2, varscan2
- OR5M10 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs756116033, COSV101595861; called by muse, mutect2, varscan2
- OR6C76 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as rs1194295932, COSV100093969; called by muse, mutect2, varscan2
- OR8D2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs376100258; called by muse, mutect2, varscan2
- OR8H1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100476850; called by muse, mutect2, varscan2
- OR8H3 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs760780743, COSV100538756, COSV100538967; called by muse, mutect2, varscan2
- OSBPL6 | c.2352T>A p.D784E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1385255931, COSV99506619; called by muse, mutect2, varscan2
- OSCAR | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99499847; called by muse, mutect2, varscan2
- OVGP1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs1254946404, COSV100868014; called by muse, mutect2, varscan2
- PBRM1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56295360; called by muse, mutect2, varscan2
- PCDH18 | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100787048; called by muse, mutect2, varscan2
- PCDH18 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV61266439; called by muse, mutect2, varscan2
- PCDHAC1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV53847233; called by muse, mutect2, varscan2
- PCDHB12 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs1339237067, COSV99506788; called by muse, mutect2, varscan2
- PCDHB13 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV53401690, COSV99506790; called by muse, mutect2, varscan2
- PCDHGA3 | c.2232C>G p.D744E | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV53960232, COSV99531413; called by muse, mutect2, varscan2
- PCDHGA6 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV99531418; called by muse, mutect2, varscan2
- PCLO | c.9721G>A p.E3241K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100427701; called by muse, mutect2, varscan2
- PDE1C | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100371133, COSV100373462; called by muse, mutect2, varscan2
- PDE5A | c.2258A>C p.E753A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV99308323; called by muse, mutect2, varscan2
- PDGFRB | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV55800077; called by muse, mutect2, varscan2
- PDZD2 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1173423820, COSV99223821; called by muse, mutect2, varscan2
- PDZRN4 | c.1982G>A p.G661E (on ENST00000402685 / NM_001164595.2; = p.G403E on NM_013377.4) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54216494; called by muse, mutect2, varscan2
- PELP1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.476); catalogued as rs1389249172, COSV99342532; called by muse, mutect2
- PEPD | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758357853, COSV99727322; called by muse, varscan2
- PHF3 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV100012927; called by muse, mutect2, varscan2
- PITPNM1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100039329; called by muse, mutect2, varscan2
- PIWIL2 | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100769223; called by muse, mutect2, varscan2
- PLA2R1 | c.955+1G>A p.X319_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99322232; called by muse, mutect2, varscan2
- PLA2R1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1558963004, COSV99322237; called by muse, mutect2, varscan2
- PLAT | c.971G>A p.W324* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99534985; called by muse, mutect2, varscan2
- PLCB1 | c.3391A>G p.I1131V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100569442; called by muse, mutect2, varscan2
- PLCB2 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs778773658, COSV99541558; called by muse, mutect2, varscan2
- PLEKHH1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773525211, COSV100232704, COSV100233033; called by muse, mutect2
- PLXNA4 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58107852; called by muse, mutect2
- PMF1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100195756; called by muse, mutect2, varscan2
- PNPLA4 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755632129, COSV101124360; called by muse, mutect2, varscan2
- PNPLA8 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993418; called by muse, mutect2, varscan2
- POLM | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1322439420, COSV99641661; called by muse, mutect2, varscan2
- PPP1R3A | c.2536G>C p.E846Q | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); catalogued as COSV99492016; called by muse, mutect2
- PPWD1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as rs1430916098, COSV99731101; called by muse, mutect2, varscan2
- PROKR2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV54086790; called by muse, mutect2, varscan2
- PROSER3 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1339082268, COSV99994461; called by muse, mutect2, varscan2
- PROX1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54778175; called by muse, mutect2, varscan2
- PTCH2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100941919; called by muse, mutect2, varscan2
- PTEN | c.437dup p.L146Ffs*34 | Frame Shift Ins (INS) | VAF 19/85 reads (22%) | catalogued as COSV64294491, COSV64305217; called by mutect2, pindel, varscan2
- PTH2R | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV99782126; called by muse, mutect2, varscan2
- PTPN1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100860563; called by muse, varscan2
- PTPN1 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.445); catalogued as COSV100860564; called by muse, varscan2
- PTPN5 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274620438, COSV100659668, COSV62124493; called by muse, mutect2, varscan2
- PTPRB | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV54245082; called by muse, mutect2
- PTPRJ | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV69249562; called by muse, mutect2
- RBFOX1 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60952710, COSV60965305; called by muse, mutect2, varscan2
- RBP5 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV99866576; called by muse, mutect2, varscan2
- RELA | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100425724; called by muse, mutect2, varscan2
- REST | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376611047; called by muse, mutect2, varscan2
- RIF1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99690116; called by muse, mutect2, varscan2
- RIMS1 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53440710; called by muse, mutect2, varscan2
- RNF148 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 161/437 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs549412357, COSV100411449; called by muse, mutect2, varscan2
- RNF216 | c.692C>T p.S231F (on ENST00000425013 / NM_207116.3; = p.S288F on NM_207111.4) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs367746074; called by muse, mutect2, varscan2
- ROBO2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs567065372, COSV59896989; called by muse, mutect2, varscan2
- ROR2 | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1189871991, COSV100995538; called by muse, mutect2, varscan2
- RPGRIP1L | c.3902C>T p.A1301V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as rs1382585193, COSV100045857; called by muse, varscan2
- RPRD2 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV100954924; called by muse, mutect2, varscan2
- RTCB | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1223798858, COSV99321930; called by muse, mutect2, varscan2
- RYR3 | c.10042G>A p.E3348K (on ENST00000389232; = p.E3349K on NM_001036.6) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as rs1278560286, COSV66788251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.2853G>A p.W951* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV101180129; called by muse, mutect2, varscan2
- SAMSN1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53469412; called by muse, mutect2, varscan2
- SBSPON | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866466373, COSV52076547; called by muse, mutect2, varscan2
- SCN10A | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.54); catalogued as rs1384093469, COSV101479254, COSV71860360; called by muse, mutect2, varscan2
- SEC23B | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV99357426; called by muse, mutect2, varscan2
- SELENOS | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101237222; called by muse, mutect2
- SEMA4A | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as CM061192, COSV100740453; called by muse, mutect2, varscan2
- SEMA4A | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs111977724, COSV61772129; called by muse, mutect2, varscan2
- SEMA5B | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99530895; called by muse, mutect2, varscan2
- SERPINA3 | c.271del p.A91Pfs*6 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as rs1329775191, COSV101261670; called by mutect2, pindel, varscan2
- SERTAD4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs746720364, COSV100882585; called by muse, mutect2, varscan2
- SETDB1 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99643832, COSV99644310; called by mutect2, varscan2
- SH3GL3 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as COSV61061661; called by muse, mutect2, varscan2
- SHPK | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56648836, COSV99843641; called by muse, mutect2, varscan2
- SI | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV100014166; called by muse, mutect2, varscan2
- SIRT2 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV99979217; called by muse, mutect2, varscan2
- SIRT6 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs758533288, COSV99313882; called by muse, varscan2
- SLC10A2 | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99807653, COSV99808173; called by muse, mutect2, varscan2
- SLC12A5 | c.2796G>A p.M932I (on ENST00000454036 / NM_001134771.2; = p.M909I on NM_020708.5) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as COSV99715406; called by muse, mutect2, varscan2
- SLC1A2 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV99553990; called by muse, mutect2, varscan2
- SLC22A3 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99278369; called by muse, mutect2, varscan2
- SLC24A5 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs774546543, COSV51050325; called by muse, mutect2, varscan2
- SLC25A30 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV100181238; called by muse, mutect2, varscan2
- SLC26A3 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV100384835; called by muse, mutect2, varscan2
- SLC43A2 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100024701; called by mutect2, varscan2
- SLC6A2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs769097694, COSV54924140; called by muse, mutect2, varscan2
- SLC6A6 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99816962; called by muse, mutect2, varscan2
- SLC7A2 | c.955C>A p.L319I (on ENST00000494857 / NM_001370338.1; = p.L359I on NM_003046.6) | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.651); catalogued as rs1361498610, COSV99134369; called by muse, mutect2, varscan2
- SLC9A4 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54831814; called by muse, mutect2, varscan2
- SLCO1A2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs1043936757, COSV100261359; called by muse, mutect2, varscan2
- SLCO5A1 | c.2413C>T p.H805Y | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.024); catalogued as COSV99479454; called by muse, mutect2, varscan2
- SLIT3 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759032960, COSV100265553; called by muse, mutect2, varscan2
- SLITRK1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65674844; called by muse, mutect2, varscan2
- SLITRK6 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68389274; called by muse, mutect2, varscan2
- SMPDL3B | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV65871390; called by muse, mutect2, varscan2
- SNED1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as rs1368132459, COSV60019262; called by muse, mutect2, varscan2
- SNTB1 | c.868T>C p.F290L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as COSV101179780; called by muse, mutect2, varscan2
- SON | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs767697655, COSV51664638; called by muse, mutect2, varscan2
- SORCS3 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV63802764, COSV63807620; called by muse, mutect2, varscan2
- SORL1 | c.6370G>A p.D2124N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52756359; called by muse, mutect2, varscan2
- SPAG17 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as rs1211648185, COSV60457658; called by muse, mutect2, varscan2
- SPATA31D1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770832493, COSV61194080; called by muse, mutect2, varscan2
- SPG11 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV99968093; called by muse, mutect2, varscan2
- SPOP | c.440A>C p.N147T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as COSV100753184; called by muse, mutect2, varscan2
- SPTA1 | c.5534G>A p.G1845E | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV63748161; called by muse, mutect2, varscan2
- SPTA1 | c.4608G>A p.R1536= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as rs371290853; called by muse, mutect2, varscan2
- SRF | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99541724; called by muse, mutect2, varscan2
- SRRM4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (1); catalogued as COSV99937792; called by muse, mutect2, varscan2
- STARD6 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447535731, COSV55619384; called by muse, mutect2, varscan2
- STXBP5L | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757487745, COSV56519058; called by muse, mutect2, varscan2
- SUPT5H | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100067778; called by muse, mutect2, varscan2
- SUSD4 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV100663512; called by muse, mutect2, varscan2
- SYNE1 | c.1021G>A p.E341K (on ENST00000367255 / NM_182961.4; = p.E348K on NM_033071.3) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs1203553546, COSV99554458; called by muse, mutect2, varscan2
- SYT1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868227414, COSV54050678; called by muse, mutect2, varscan2
- SYTL3 | c.1372G>A p.V458I (on ENST00000611299 / NM_001242394.1; = p.V390I on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as rs750948120, COSV99791555; called by muse, mutect2, varscan2
- TACC1 | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392975; called by muse, mutect2, varscan2
- TACC3 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV100508515, COSV100508663; called by muse, mutect2, varscan2
- TANC1 | c.4978C>T p.L1660F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.143); catalogued as COSV99713129; called by muse, mutect2, varscan2
- TARDBP | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | catalogued as COSV99534036; called by muse, mutect2, varscan2
- TBX4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV99539904; called by muse, mutect2, varscan2
- TEK | c.3049A>G p.T1017A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV101193178; called by muse, mutect2, varscan2
- TET1 | c.6313C>T p.P2105S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101018675, COSV65389870; called by muse, mutect2, varscan2
- TEX11 | c.955G>A p.E319K (on ENST00000344304; = p.E304K on NM_031276.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1312102683, COSV100721353; called by muse, mutect2, varscan2
- TGDS | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1269740294, COSV99724986; called by muse, mutect2, varscan2
- THEMIS | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs868678386, COSV64070565; called by muse, mutect2, varscan2
- THRB | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs756399184, COSV62841821; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, mutect2, varscan2
- THUMPD2 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.5); catalogued as COSV99571958; called by muse, mutect2, varscan2
- TLR8 | c.2174C>T p.S725F (on ENST00000218032 / NM_138636.5; = p.S743F on NM_016610.4) | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as rs1173264527, COSV99486800; called by muse, mutect2, varscan2
- TMCO5A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.996); catalogued as rs756633826, COSV60464273; called by muse, mutect2, varscan2
- TMEM127 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.627); catalogued as rs751854293, COSV99302478; called by muse, mutect2, varscan2
- TMEM74 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1347318290, COSV99865426; called by muse, mutect2, varscan2
- TMIGD2 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as rs777592664, COSV100010139; called by muse, mutect2, varscan2
- TNC | c.5935C>T p.P1979S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV100405028; called by muse, mutect2, varscan2
- TNPO1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1313940518, COSV100473035; called by muse, mutect2, varscan2
- TNS3 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV100234824; called by muse, mutect2, varscan2
- TOMM7 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100626941; called by muse, mutect2, varscan2
- TOX2 | c.1400C>T p.P467L (on ENST00000358131 / NM_001098798.2; = p.P443L on NM_032883.3) | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV100363384; called by muse, mutect2, varscan2
- TRIML1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100205729; called by muse, mutect2, varscan2
- TSC2 | c.4292C>T p.S1431L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs375785710, COSV51920651; ClinVar: benign; called by muse, mutect2
- TSHZ2 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.036); catalogued as COSV100295445, COSV61590888; called by muse, mutect2, varscan2
- TSLP | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs867610850, COSV100789155; called by muse, mutect2, varscan2
- TSSK1B | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV66814765; called by muse, mutect2, varscan2
- TTN | c.41513C>T p.P13838L (on ENST00000591111; = p.P6414L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100595728; called by muse, mutect2, varscan2
- TTN | c.23156C>T p.S7719L (on ENST00000591111; = p.S6792L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | PolyPhen benign (0); catalogued as rs200598509, COSV59999690; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.20962G>A p.E6988K (on ENST00000591111; = p.E6061K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | PolyPhen benign (0.099); catalogued as rs867359588, COSV60255234; called by muse, mutect2, varscan2
- TTN | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 27/131 reads (21%) | PolyPhen probably damaging (0.945); catalogued as COSV59889839; called by muse, mutect2, varscan2
- UGT1A4 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100529623; called by muse, mutect2, varscan2
- UNC13A | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99407192; called by muse, mutect2, varscan2
- UNC13C | c.2732A>G p.E911G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99512120; called by muse, mutect2, varscan2
- UTP20 | c.6986C>T p.P2329L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99880856, COSV99881859; called by muse, mutect2, varscan2
- UTP25 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV101504727; called by muse, mutect2, varscan2
- VPS13D | c.5807G>A p.R1936Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs747867326, COSV99165516, COSV99167371; called by muse, mutect2, varscan2
- VPS13D | c.11086G>A p.E3696K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV99165520; called by muse, mutect2
- WEE1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs1207216979, COSV100219599; called by muse, mutect2, varscan2
- WFDC8 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250303; called by muse, mutect2, varscan2
- XKR3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100509134; called by muse, mutect2, varscan2
- XPO5 | c.2770C>T p.H924Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1426728116, COSV99540437; called by muse, mutect2
- ZBTB37 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs778284727, COSV100774526; called by muse, mutect2, varscan2
- ZC3H12C | c.59dup p.N20Kfs*10 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | catalogued as rs1213644414; called by mutect2, pindel, varscan2
- ZC3H18 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as rs776346988, COSV56327553; called by muse, mutect2, varscan2
- ZFP90 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV101238704; called by muse, mutect2, varscan2
- ZNF136 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100677874; called by muse, mutect2
- ZNF236 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV99469169; called by muse, mutect2
- ZNF287 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV101209330; called by muse, mutect2
- ZNF382 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99497481; called by muse, mutect2, varscan2
- ZNF496 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV54173341, COSV99665210; called by muse, mutect2, varscan2
- ZNF557 | c.32-4C>T | Splice Region (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99422265; called by muse, mutect2, varscan2
- ZNF589 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1325942239, COSV100685546; called by muse, mutect2, varscan2
- ZNF711 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99340681; called by muse, mutect2, varscan2
- ZNF790 | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100764759; called by muse, mutect2, varscan2
- ZNF99 | c.2225T>C p.F742S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101233718; called by muse, mutect2, varscan2
- ZNF99 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233719; called by muse, mutect2, varscan2
- ZSWIM8 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV101289805; called by muse, mutect2
- CHGB | c.994_996delinsCA p.Y332Qfs*14 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2*
- DNAH5 | c.3382_3396del p.N1128_K1132del | In Frame Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- HMCN1 | c.11141del p.N3714Tfs*2 | Frame Shift Del (DEL) | VAF 33/294 reads (11%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PIGW | c.959T>G p.V320G | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POTEA | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TARS1 | c.2074_2075dup p.D692Efs*58 | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- TGIF1 | c.416dup p.P140Afs*62 (on ENST00000330513 / NM_001374396.1; = p.P160Afs*62 on NM_003244.4) | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- TMEM236 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 149/424 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- TPTE | c.700G>A p.G234R (on ENST00000618007 / NM_199261.4; = p.G216R on NM_199259.4) | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- TRGV5 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- AADAC | c.1188G>A p.K396= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99233099; called by muse, mutect2, varscan2
- AARS1 | c.2697C>T p.I899= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99933225; called by muse, mutect2, varscan2
- ABCG4 | c.1398G>A p.A466= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as rs774866555, COSV56646628; called by muse, mutect2, varscan2
- AC134980.2 | c.765C>T p.I255= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100171458, COSV60906568; called by mutect2, varscan2
- ACACB | c.2046T>C p.G682= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100622373; called by muse, mutect2
- ACSM5 | c.720C>T p.V240= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs767280617, COSV100088486; called by mutect2, varscan2
- ADAM18 | c.1188G>A p.G396= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV55845634; called by muse, mutect2, varscan2
- ADAM7 | c.2202C>T p.F734= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1275032789, COSV51546567; called by muse, mutect2
- ADAMTS18 | c.3264G>A p.L1088= | Silent (SNP) | VAF 73/275 reads (27%) | catalogued as COSV99271296; called by muse, mutect2, varscan2
- ADCY8 | c.1803C>T p.I601= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs771961643, COSV53900335; called by muse, mutect2, varscan2
- ADD2 | c.306C>T p.F102= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV52473259; called by muse, mutect2, varscan2
- AKAP3 | c.948C>T p.I316= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV57417314; called by muse, mutect2, varscan2
- AMPD2 | c.1074C>T p.I358= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99857392; called by muse, mutect2, varscan2
- ANGPTL2 | c.660C>T p.A220= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99400904; called by muse, mutect2, varscan2
- ANKRD12 | c.750T>C p.D250= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100040784; called by muse, mutect2, varscan2
- ANKZF1 | c.957C>T p.P319= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV55477407; called by muse, mutect2, varscan2
- ANO2 | c.1923C>T p.F641= (on ENST00000356134 / NM_001278597.3; = p.F645= on NM_001278596.3) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100499896; called by muse, mutect2
- ANXA3 | c.459G>A p.R153= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV99363533; called by muse, mutect2, varscan2
- APLNR | c.775C>T p.L259= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV57242964, COSV99951266; called by muse, mutect2, varscan2
- APOBEC2 | c.423G>A p.K141= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99079228, COSV99775296; called by muse, mutect2, varscan2
- ARHGAP22 | c.603C>T p.N201= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV99984521; called by muse, mutect2, varscan2
- ASL | c.336C>T p.S112= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100508827; called by muse, mutect2, varscan2
- ATP6V1G3 | c.111G>A p.K37= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs1371294574, COSV99810700; called by muse, mutect2, varscan2
- ATXN7L3 | c.669C>T p.S223= (on ENST00000389384 / NM_001382309.1; = p.S230= on NM_001382308.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV60228228; called by muse, mutect2, varscan2
- BHMT2 | c.609C>T p.I203= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99669955; called by muse, mutect2
- BLVRB | c.135C>T p.P45= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1255207261, COSV54570164; called by muse, mutect2
- BRPF1 | c.978T>C p.R326= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100121108; called by muse, mutect2, varscan2
- BRPF3 | c.2068C>T p.L690= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100325576; called by muse, mutect2, varscan2
- C10orf62 | c.546C>T p.F182= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs757009497, COSV101035219; called by muse, mutect2, varscan2
- C17orf75 | c.387C>T p.F129= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1286181560, COSV99858517; called by muse, mutect2, varscan2
- C1S | c.345C>T p.S115= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100196383; called by muse, mutect2
- C2orf16 | c.1725G>A p.Q575= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100820668; called by muse, mutect2, varscan2
- C3orf56 | c.342C>T p.L114= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as COSV101228926; called by muse, mutect2, varscan2
- CACNA2D1 | c.1806A>G p.K602= (on ENST00000356253 / NM_001366867.1; = p.K583= on NM_000722.4) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs1472220449, COSV100666002; called by muse, mutect2, varscan2
- CAPN10 | c.264C>T p.L88= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99549969; called by muse, mutect2, varscan2
- CAT | c.1458C>T p.H486= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs774362693, COSV99573112; called by muse, mutect2, varscan2
- CCR3 | c.990C>T p.F330= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV62463550; called by muse, mutect2, varscan2
- CDK3 | c.466C>T p.L156= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100044009; called by muse, mutect2, varscan2
- CFHR5 | c.1629C>T p.F543= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs762380054, COSV99887996; called by muse, mutect2, varscan2
- CHD6 | c.1398G>A p.L466= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV100497801; called by muse, mutect2, varscan2
- CHST15 | c.1131C>T p.F377= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60564433; called by muse, mutect2, varscan2
- CLEC14A | c.1062G>A p.T354= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100643505, COSV60562416; called by muse, mutect2, varscan2
- CNTN5 | c.2484C>T p.S828= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99673230; called by muse, mutect2, varscan2
- COL5A1 | c.2572C>T p.L858= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100879556; called by muse, mutect2, varscan2
- CORIN | c.2286G>A p.G762= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as COSV99902947; called by muse, mutect2, varscan2
- CPNE4 | c.405G>A p.G135= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV70190551; called by muse, mutect2, varscan2
- CPO | c.276A>G p.Q92= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as rs930942485, COSV99786351, COSV99786751; called by muse, mutect2, varscan2
- CRP | c.417G>A p.L139= | Silent (SNP) | VAF 69/266 reads (26%) | catalogued as COSV99660453; called by muse, mutect2, varscan2
- CSMD3 | c.2250G>A p.T750= (on ENST00000297405 / NM_001363185.1; = p.T646= on NM_052900.3) | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs144040661, COSV52178991, COSV52185698; called by muse, mutect2, varscan2
- CUL1 | c.885C>T p.L295= | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as COSV100296443; called by muse, mutect2, varscan2
- CXCL9 | c.288G>A p.K96= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV53578565, COSV99345683; called by muse, mutect2
- DDX60L | c.2367G>C p.G789= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV99487006; called by muse, varscan2
- DEFA3 | c.138C>T p.S46= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100590621, COSV100590645; called by mutect2, varscan2
- DLG1 | c.2355C>T p.N785= (on ENST00000419354 / NM_001290983.1; = p.N807= on NM_004087.2) | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as COSV100014665; called by muse, mutect2, varscan2
- DNAH17 | c.9567C>T p.I3189= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs146469560; called by muse, mutect2, varscan2
- DNAH5 | c.4863C>T p.I1621= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV99445440; called by muse, mutect2, varscan2
- DNAH9 | c.13431G>A p.L4477= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1291443077, COSV99304282; called by muse, mutect2, varscan2
- FAM135B | c.2976C>T p.S992= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs751949889, COSV52710230, COSV52728278; called by muse, mutect2, varscan2
- FAM160A2 | c.2490C>T p.A830= (on ENST00000449352 / NM_001098794.2; = p.A844= on NM_032127.4) | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV99791733; called by muse, mutect2, varscan2
- FAM83E | c.873C>T p.L291= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs369917515, COSV99572064, COSV99572149; called by muse, mutect2, varscan2
- FBXL18 | c.1686C>T p.S562= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs566784860, COSV66107710; called by muse, mutect2, varscan2
- FCER1A | c.519C>T p.T173= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100929246; called by muse, mutect2, varscan2
- FMN2 | c.4920G>A p.E1640= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV100143020, COSV60425930; called by muse, mutect2, varscan2
- FNIP2 | c.2610C>T p.I870= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100032203; called by muse, mutect2, varscan2
- FREM1 | c.4905C>T p.S1635= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs376327068, COSV101083859; called by muse, mutect2, varscan2
- FRY | c.4101C>T p.I1367= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs753627910, COSV100968820; called by muse, mutect2, varscan2
- FSIP2 | c.20574G>A p.K6858= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs757517558, COSV100554097; called by muse, mutect2, varscan2
- FTMT | c.360G>A p.R120= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs375767223; called by muse, mutect2, varscan2
- GFRAL | c.396G>A p.L132= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV100474656, COSV61231084; called by muse, mutect2, varscan2
- GGA2 | c.1812C>T p.F604= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs761387519, COSV100564545; called by muse, mutect2, varscan2
- GIGYF2 | c.2847C>T p.I949= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs775636461, COSV101003918; called by muse, mutect2, varscan2
- GJA8 | c.108C>T p.I36= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs781829394, COSV53788493, COSV53788636; called by muse, mutect2, varscan2
- GRIN2A | c.3684C>T p.F1228= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs1247091391, COSV100408423; called by muse, mutect2, varscan2
- GSG1 | c.543C>T p.F181= (on ENST00000651961 / NM_001080555.4; = p.P187S on NM_031289.5) | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV99545402; called by muse, mutect2, varscan2
- GTF3A | c.426C>T p.T142= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100820182; called by muse, varscan2
- HIF3A | c.1836C>T p.F612= (on ENST00000377670 / NM_152795.4; = p.F543= on NM_022462.4) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1222732783, COSV99355537; called by muse, mutect2, varscan2
- HKDC1 | c.1410C>T p.I470= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs778487213, COSV100664383; called by muse, mutect2, varscan2
- HLA-DQB1 | c.639G>A p.Q213= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100891086; called by muse, mutect2, varscan2
- HNF4A | c.513G>A p.G171= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV100291083; called by muse, mutect2, varscan2
- HTR2C | c.642C>T p.F214= | Silent (SNP) | VAF 107/336 reads (32%) | catalogued as rs368641796, COSV52202768, COSV52205141; called by muse, mutect2, varscan2
- HTR2C | c.961C>T p.L321= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV99348196; called by muse, mutect2, varscan2
- HTRA3 | c.651C>T p.A217= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100246211; called by muse, mutect2, varscan2
- IDH2 | c.567C>T p.A189= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs780132243, COSV100343355; called by muse, mutect2, varscan2
- IFT140 | c.199C>T p.L67= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV68486740; called by muse, mutect2, varscan2
- IGSF10 | c.1908C>T p.T636= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as rs1346562619, COSV56785598; called by muse, mutect2, varscan2
- IGSF9 | c.1287C>T p.F429= (on ENST00000368094 / NM_001135050.2; = p.F413= on NM_020789.4) | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV63641527; called by muse, mutect2, varscan2
- IL18R1 | c.564C>T p.F188= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1395171640, COSV99294891; called by muse, varscan2
- INPP5J | c.1263C>T p.P421= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs551093566, COSV100459469, COSV58512249; called by muse, mutect2, varscan2
- INTS6L | c.1884C>T p.S628= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV100878024; called by muse, mutect2, varscan2
- ITGA4 | c.1818G>A p.K606= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1453852159, COSV52000159, COSV99275787; called by muse, mutect2, varscan2
- ITGB3 | c.1467G>A p.G489= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV101457546; called by muse, mutect2, varscan2
- JCAD | c.3288G>A p.V1096= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV64761275; called by muse, mutect2, varscan2
- JRK | c.156C>T p.L52= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs782773474, COSV70629861; called by muse, mutect2, varscan2
- KCNC2 | c.1776G>A p.R592= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV54376190; called by muse, mutect2, varscan2
- KCNH6 | c.915C>T p.L305= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV59000322; called by muse, mutect2, varscan2
- KCNH6 | c.2856G>A p.L952= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100120806; called by muse, mutect2, varscan2
- KCNK16 | c.411G>A p.V137= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100949084; called by muse, mutect2, varscan2
- KCNQ3 | c.2373C>T p.S791= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1223970817, COSV101195479; called by muse, mutect2, varscan2
- KDR | c.690G>A p.P230= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs762050543, COSV99816784; called by muse, mutect2, varscan2
- KIF4B | c.3430C>T p.L1144= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV101469194; called by muse, mutect2, varscan2
- KIZ | c.1908C>T p.I636= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99851858; called by muse, mutect2, varscan2
- KL | c.1686G>A p.G562= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV101199014; called by muse, mutect2, varscan2
- KLHL13 | c.1191G>A p.Q397= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99451047; called by muse, mutect2, varscan2
- KMT2D | c.2679C>T p.P893= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99977823; called by muse, mutect2, varscan2
- LEPR | c.3405G>A p.K1135= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100847887; called by muse, mutect2, varscan2
- LEXM | c.681A>T p.R227= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100827478; called by muse, mutect2
- LMTK2 | c.4023C>T p.A1341= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99806075; called by muse, mutect2, varscan2
- LRG1 | c.540C>T p.P180= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV56705861; called by muse, varscan2
- LRP2 | c.13434C>T p.T4478= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV55580892; called by muse, mutect2, varscan2
- LRRC32 | c.1938C>T p.A646= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs963222602, COSV99476704; called by muse, mutect2, varscan2
- LRRC37B | c.1833C>T p.S611= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100496044; called by muse, mutect2, varscan2
- LRRC4B | c.1497C>T p.P499= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1434657460, COSV100975841, COSV65350297; called by muse, mutect2
- LRRIQ4 | c.810G>A p.E270= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100540105; called by muse, mutect2, varscan2
- LUZP4 | c.861C>T p.L287= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV100904830, COSV100904835; called by muse, mutect2, varscan2
- LY6H | c.375G>A p.G125= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100713850, COSV61370677; called by muse, mutect2
- LYPD4 | c.201C>T p.F67= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV58028455; called by muse, mutect2, varscan2
- MAP1A | c.4867C>T p.L1623= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100288118; called by muse, mutect2, varscan2
- MDN1 | c.9606C>T p.H3202= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs115404561, COSV101020796; called by muse, mutect2, varscan2
- MEGF8 | c.7563C>T p.V2521= (on ENST00000251268 / NM_001271938.2; = p.V2454= on NM_001410.3) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99234564; called by muse, mutect2
- MFSD12 | c.1035C>T p.F345= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs371396662; called by muse, varscan2
- MFSD4A | c.891G>A p.R297= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV65656305; called by muse, mutect2, varscan2
- MTUS2 | c.1038G>A p.R346= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101462084; called by muse, mutect2, varscan2
- MUC16 | c.39852C>T p.F13284= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV66692054; called by muse, mutect2
- MUC16 | c.31854C>T p.F10618= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1310443038, COSV67465444; called by muse, mutect2, varscan2
- MYCBP2 | c.10161A>T p.T3387= (on ENST00000357337; = p.T3425= on NM_015057.5) | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100629297; called by muse, mutect2, varscan2
- MYH13 | c.2286C>T p.F762= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs762711763, COSV52834705; called by muse, mutect2, varscan2
- MYH13 | c.819C>T p.S273= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV52820762, COSV52822638; called by muse, mutect2, varscan2
- MYH2 | c.3984G>A p.E1328= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99819322; called by muse, mutect2, varscan2
- MYO1F | c.1623G>A p.R541= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1293725569, COSV57791532; called by muse, mutect2, varscan2
- MYO1G | c.99C>T p.F33= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV51855653; called by muse, mutect2, varscan2
- MYOM2 | c.762A>G p.E254= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV100036742; called by muse, mutect2, varscan2
- NDST4 | c.1476C>T p.P492= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99995549, COSV99997963; called by muse, mutect2, varscan2
- NGRN | c.840C>T p.F280= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs774758971, COSV100517867, COSV58961011; called by muse, mutect2, varscan2
- NLRP11 | c.1122T>C p.L374= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100789639; called by muse, mutect2, varscan2
- NMUR2 | c.342C>T p.F114= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs770598805, COSV54920304; called by muse, mutect2, varscan2
- NPHP4 | c.2058C>T p.V686= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100976731; called by muse, mutect2, varscan2
- NPR1 | c.1896C>T p.D632= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs755013101, COSV100901964; called by muse, mutect2, varscan2
- NUDT10 | c.90G>A p.E30= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100726781, COSV62854178; called by muse, mutect2, varscan2
- OAS3 | c.630C>T p.Y210= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99966095; called by muse, mutect2, varscan2
- OBSCN | c.12504G>A p.A4168= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs562134549, COSV52827615, COSV52840811; called by muse, mutect2, varscan2
- OOEP | c.228G>A p.T76= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100949790; called by muse, mutect2
- OPALIN | c.237C>T p.P79= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100959572; called by muse, mutect2, varscan2
- OR1N1 | c.336C>T p.F112= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV59196075; called by muse, mutect2, varscan2
- OR2G3 | c.726C>T p.S242= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100180486; called by muse, mutect2, varscan2
- OR2W3 | c.642C>T p.I214= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV64456172; called by muse, mutect2, varscan2
- OR2Z1 | c.618C>T p.I206= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV60692728; called by muse, mutect2, varscan2
- OR4F6 | c.93C>T p.F31= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV100186803; called by muse, mutect2, varscan2
- OR4K13 | c.588G>A p.Q196= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs775832706, COSV100237641, COSV59859632; called by muse, mutect2, varscan2
- OR4X1 | c.249C>T p.S83= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100186558; called by muse, mutect2, varscan2
- OR51B5 | c.138C>T p.L46= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV56175703; called by muse, mutect2, varscan2
- OR51D1 | c.72C>T p.F24= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV62913866; called by muse, mutect2, varscan2
- OR52E8 | c.675G>A p.R225= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs267603034, COSV101190008; called by muse, mutect2, varscan2
- OR5B12 | c.771C>T p.Y257= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs781133082, COSV100222340; called by muse, mutect2, varscan2
- OR5I1 | c.261C>T p.F87= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1407525658, COSV56885617; called by mutect2, varscan2
- OR7C2 | c.219C>T p.F73= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV50182207; called by muse, mutect2
- OR7G2 | c.585C>T p.I195= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59688391; called by muse, mutect2, varscan2
- OR8A1 | c.273C>T p.I91= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99420337; called by muse, mutect2
- OR8G1 | c.621C>T p.I207= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100422233; called by muse, mutect2, varscan2
- ORC1 | c.1275G>A p.E425= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV100856589; called by muse, mutect2, varscan2
- OTOR | c.159G>A p.P53= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs150118718, COSV99856118; called by muse, mutect2, varscan2
- P3H1 | c.612C>T p.P204= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV99354860; called by muse, mutect2, varscan2
- PAK5 | c.330G>A p.Q110= | Silent (SNP) | VAF 88/213 reads (41%) | catalogued as COSV100781116; called by muse, mutect2, varscan2
- PANK1 | c.1038C>T p.F346= (on ENST00000307534 / NM_148977.2; = p.F121= on NM_138316.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs371878757; called by muse, mutect2
- PAPLN | c.3699G>A p.R1233= (on ENST00000554301; = p.R1206= on NM_173462.4) | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1274417149, COSV99389119; called by muse, mutect2, varscan2
- PCDHB11 | c.2313C>T p.I771= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs368891553; called by muse, mutect2, varscan2
- PCDHB14 | c.1581C>T p.F527= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs192565798, COSV53389035; called by muse, mutect2, varscan2
- PCDHB15 | c.2343G>A p.R781= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99178824; called by muse, mutect2, varscan2
- PCDHGA6 | c.852T>A p.I284= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99531426; called by muse, mutect2, varscan2
- PCDHGB6 | c.160C>T p.L54= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs773344794, COSV99531429; called by muse, mutect2, varscan2
- PGBD2 | c.843C>T p.S281= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100251865; called by muse, mutect2, varscan2
- PLD6 | c.453C>T p.D151= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100387559; called by muse, mutect2, varscan2
- PPM1N | c.1107G>A p.R369= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55592441; called by muse, mutect2
- PPP1R26 | c.867C>T p.F289= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV100777998; called by muse, mutect2, varscan2
- PPP1R3F | c.1233G>A p.Q411= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99278442; called by muse, mutect2, varscan2
- PRAMEF15 | c.315G>A p.L105= | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as rs1157929919; called by muse, mutect2, varscan2
- PRODH2 | c.945G>A p.A315= (on ENST00000301175; = p.A239= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs749831811, COSV56558963, COSV56561427; called by muse, mutect2, varscan2
- PROM2 | c.1305G>T p.V435= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1427865143, COSV100468692; called by muse, mutect2, varscan2
- PSMC3 | c.651C>T p.I217= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100099311; called by muse, mutect2, varscan2
- PTPRF | c.1683C>T p.F561= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs778116534, COSV63448675; called by muse, mutect2, varscan2
- RANBP2 | c.6774C>T p.F2258= | Silent (SNP) | VAF 58/418 reads (14%) | catalogued as COSV51700267; called by muse, mutect2, varscan2
- RAP1GAP2 | c.135C>T p.S45= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs747525100, COSV99622411; called by muse, mutect2, varscan2
- RIPOR3 | c.768C>T p.I256= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV99245927; called by muse, mutect2, varscan2
- RNF157 | c.1407C>T p.L469= | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as rs143082385; called by muse, mutect2, varscan2
- RNF17 | c.537G>A p.T179= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs267603788, COSV55039615; called by muse, mutect2, varscan2
- RPS6KA5 | c.1584T>A p.L528= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100002157; called by muse, mutect2, varscan2
- RYR3 | c.6612C>T p.F2204= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs369092039; called by muse, mutect2, varscan2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2, varscan2
- SBF1 | c.1506C>T p.P502= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1472270554, COSV100817489, COSV62370412; called by muse, mutect2, varscan2
- SBSPON | c.726A>C p.G242= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99817343; called by muse, mutect2, varscan2
- SCN11A | c.549C>T p.F183= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV56567084; called by muse, mutect2, varscan2
- SCN5A | c.2493C>T p.I831= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV61139547; called by muse, mutect2, varscan2
- SEC24A | c.2649A>G p.L883= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV101295016; called by muse, mutect2, varscan2
- SEC24C | c.1305C>T p.F435= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100226537; called by muse, mutect2, varscan2
- SFTPD | c.447C>T p.A149= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100954478; called by muse, mutect2, varscan2
- SIGLEC14 | c.735C>T p.F245= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV55778163; called by muse, mutect2, varscan2
- SLC10A2 | c.219C>T p.L73= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99807656; called by muse, mutect2, varscan2
- SLC16A1 | c.757C>T p.L253= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100855841; called by muse, mutect2, varscan2
- SLC17A8 | c.1488C>T p.I496= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100035211; called by muse, mutect2, varscan2
- SLC30A8 | c.174G>A p.K58= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV69969283; called by muse, mutect2, varscan2
- SLC35B2 | c.48C>T p.S16= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99240896; called by muse, mutect2, varscan2
- SLC35D3 | c.1065C>T p.P355= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs775326542, COSV100090396; called by muse, mutect2, varscan2
- SLC9A4 | c.1822C>T p.L608= | Silent (SNP) | VAF 24/273 reads (9%) | catalogued as COSV54829182; called by muse, mutect2
- SNAP47 | c.345C>T p.I115= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100247928; called by muse, mutect2, varscan2
- SNAP47 | c.346C>T p.L116= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100248296, COSV59919767; called by muse, mutect2, varscan2
- SNUPN | c.180C>T p.N60= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100419291; called by muse, mutect2, varscan2
- SOHLH1 | c.525C>T p.A175= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100039848; called by muse, mutect2, varscan2
- SORL1 | c.1806G>A p.S602= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs781728057, COSV52752370; called by muse, mutect2, varscan2
- SPHKAP | c.417C>T p.L139= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100763730; called by muse, mutect2, varscan2
- SPOP | c.441C>T p.N147= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs767050824, COSV100753183; called by muse, mutect2, varscan2
- SRGAP1 | c.366G>A p.L122= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV61901157, COSV61903870; called by muse, mutect2, varscan2
- SSU72 | c.279C>T p.P93= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as COSV99357160; called by muse, mutect2, varscan2
- ST3GAL5 | c.393C>T p.V131= (on ENST00000377332; = p.V171= on NM_003896.4) | Silent (SNP) | VAF 31/200 reads (16%) | catalogued as COSV100088249; called by muse, mutect2, varscan2
- STC1 | c.297C>T p.I99= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs779487178, COSV51688472; called by muse, mutect2, varscan2
- SUPT5H | c.3195C>T p.V1065= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100067776; called by muse, mutect2, varscan2
- TBC1D3F | c.1002G>A p.R334= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- TIAM1 | c.3216A>G p.K1072= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as COSV99732988; called by muse, mutect2, varscan2
- TNFSF15 | c.627C>T p.F209= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1398480981, COSV100928306; called by muse, mutect2, varscan2
- TNFSF15 | c.21G>A p.L7= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV65012151; called by muse, mutect2, varscan2
- TOMM7 | c.126C>A p.P42= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs141512738; called by muse, mutect2, varscan2
- TP53BP1 | c.2718C>T p.F906= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1446766361, COSV99779846; called by muse, mutect2, varscan2
- TSTD2 | c.1089G>A p.R363= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52249697; called by muse, mutect2, varscan2
- TTN | c.68454G>A p.E22818= (on ENST00000591111; = p.E15394= on NM_003319.4) | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100595725; called by muse, mutect2, varscan2
- TTN | c.8736C>T p.S2912= (on ENST00000591111; = p.S2866= on NM_003319.4) | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100595734; called by muse, mutect2, varscan2
- TUBA3C | c.1311G>A p.V437= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV101313838; called by muse, mutect2, varscan2
- TUBGCP5 | c.663C>T p.V221= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- UBR4 | c.12325C>T p.L4109= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs1230763728, COSV100920269; called by muse, mutect2, varscan2
- UBR4 | c.12324C>T p.F4108= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as COSV100920271; called by muse, mutect2, varscan2
- UBXN7 | c.687C>T p.S229= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs368684662; called by muse, mutect2, varscan2
- USH2A | c.4851T>A p.A1617= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100229471, COSV56338916, COSV56351150, COSV56369282; called by muse, mutect2, varscan2
- USP43 | c.879C>T p.F293= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV53304602; called by muse, mutect2, varscan2
- VPS13D | c.5808G>A p.R1936= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs144107900; called by muse, mutect2, varscan2
- VRTN | c.1947G>A p.T649= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs777175973, COSV56439410; called by muse, mutect2, varscan2
- WNK3 | c.1545G>A p.G515= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100670838; called by muse, mutect2, varscan2
- WNT5B | c.813C>T p.T271= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1202017608, COSV100148574; called by muse, mutect2, varscan2
- XPO5 | c.2769C>T p.L923= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99540443; called by muse, mutect2
- XRRA1 | c.1927C>T p.L643= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100213212; called by muse, mutect2, varscan2
- ZADH2 | c.909C>T p.F303= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100463280; called by muse, mutect2, varscan2
- ZBED2 | c.558G>A p.R186= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99342380; called by muse, mutect2, varscan2
- ZBED2 | c.57C>T p.D19= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99342382; called by muse, mutect2, varscan2
- ZFHX4 | c.7434C>T p.S2478= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV50492758; called by muse, mutect2, varscan2
- ZNF143 | c.993C>T p.F331= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs147334022; called by muse, mutect2, varscan2
- ZNF222 | c.1170C>T p.L390= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV99496143; called by muse, mutect2, varscan2
- ZNF319 | c.1155C>T p.H385= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99539996; called by muse, mutect2, varscan2
- ZNF341 | c.1149C>T p.T383= (on ENST00000375200 / NM_001282935.1; = p.T376= on NM_032819.4) | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as rs780151851, COSV61008869; called by muse, mutect2, varscan2
- ZNF609 | c.756C>T p.S252= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100440420; called by muse, mutect2, varscan2
- ZNF628 | c.570C>T p.N190= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1253758537, COSV99219793; called by muse, mutect2, varscan2
- ZNF654 | c.3168T>A p.L1056= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV100525612; called by muse, mutect2, varscan2
- ZNF786 | c.846C>T p.T282= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs764975430, COSV100302674; called by muse, mutect2, varscan2
- ZNF813 | c.708C>T p.I236= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV67176116; called by muse, mutect2, varscan2
- DCHS2 | n.5847G>A | RNA (SNP) | VAF 42/134 reads (31%) | catalogued as COSV100601133; called by muse, mutect2, varscan2
- DCHS2 | n.3849C>T | RNA (SNP) | VAF 53/127 reads (42%) | catalogued as COSV100601134; called by muse, mutect2, varscan2
- DSCR4 | n.429G>A | RNA (SNP) | VAF 24/97 reads (25%) | catalogued as COSV60299491; called by muse, mutect2, varscan2
- KLK8 | c.71-27G>A | Intron (SNP) | VAF 17/66 reads (26%) | catalogued as rs776181926, COSV99143885; called by muse, mutect2, varscan2
- LRIT1 | c.*2G>A | 3'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as rs765679672, COSV100927991, COSV100928010; called by muse, mutect2, varscan2
- MEST | c.181+618G>A | Intron (SNP) | VAF 8/61 reads (13%) | catalogued as rs1393189017, COSV56228036; called by muse, mutect2, varscan2
- MIR135A2 | chr12:97563898 del ATTGTGAAAAATCATCAACTAAGAAGGGGCCATCAGTATAGAG | RNA (DEL) | VAF 6/77 reads (8%) | called by mutect2, pindel
- MIR520A | n.34C>T | RNA (SNP) | VAF 63/192 reads (33%) | catalogued as rs371672116; called by muse, mutect2, varscan2
- MYL3 | chr3:46832976 C>T | 3'Flank (SNP) | VAF 13/47 reads (28%) | catalogued as COSV101451246, COSV70133443; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2432_-549+2434del | Intron (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel*, varscan2
- NDUFA13 | chr19:19516168 C>T | 5'Flank (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99388918; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516169 C>T | 5'Flank (SNP) | VAF 19/61 reads (31%) | catalogued as rs766015800, COSV99388920; called by muse, mutect2, varscan2
- OR4S2 | c.-2C>T | 5'UTR (SNP) | VAF 29/50 reads (58%) | catalogued as rs1474111258, COSV100412562; called by muse, mutect2, varscan2
- PIK3CD | c.-138+2544C>T | Intron (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101055125; called by muse, mutect2, varscan2
- RRM2 | n.681C>T | RNA (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- SCN2A | c.606-144C>T | Intron (SNP) | VAF 29/116 reads (25%) | catalogued as rs558474027, COSV51840169; called by muse, mutect2, varscan2
- SSPOP | n.3108C>T | RNA (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100022151; called by muse, mutect2, varscan2
- TRIO | c.7632+722C>T | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs779267083, COSV100702435; called by muse, mutect2, varscan2
- TTN | c.10360+3190G>A | Intron (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100595733, COSV60327532; called by muse, mutect2, varscan2
- ZNF658B | n.2305C>T | RNA (SNP) | VAF 31/89 reads (35%) | called by mutect2, varscan2
